Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9U7, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9U7-01A (Primary Tumor).

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

“Uterine cervix biopsy”:

Poorly differentiated and invasive squamous cell carcinoma.

Angiolymphatic and perineural infiltration not observed.

ICD-O-3

Carcinoma, squamous cell NOS
807013

Site: Cervix NOS
C539

W 3/7/14

Source: NCI Genomic Data Commons file db14c0d9-e6c9-47a9-8090-6ea7e3824f18 (TCGA-VS-A9U7.3FB4D6F8-6625-49A7-AA2C-533FB9EC9310.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).